Somatic mutation profile of tumor specimen TCGA-JY-A93E-01A (aliquot TCGA-JY-A93E-01A-11D-A37C-09) from TCGA case TCGA-JY-A93E, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 61.4 years (22,427 days).
Specimen TCGA-JY-A93E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 14fa84a0-d96d-43e8-9ebb-dd91c1a4f657.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-JY-A93E-10A (Blood Derived Normal), aliquot TCGA-JY-A93E-10A-01D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92ed2c89-f4cc-4689-833b-d838d8198665

The open-access MAF lists 201 somatic variants for this specimen: 145 protein-altering or splice-affecting, 48 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 130, Silent 48, Nonsense Mutation 6, Frame Shift Del 3, Frame Shift Ins 3, Splice Site 2, Intron 2, 3'UTR 2, RNA 2, 5'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | hotspot (GDC flag); catalogued as rs121913344, CM971506, COSV52662281, COSV52987117, COSV53852813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCG8 | c.1852G>A p.G618R | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as rs200005264, COSV55391981; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN2 | c.1384G>T p.A462S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.985); catalogued as rs376923220, CM1410879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANXA7 | c.833G>T p.R278L (on ENST00000372919 / NM_001320880.2; = p.R256L on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.561); catalogued as COSV65823056; called by muse, mutect2
- ARHGAP36 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs185166986, COSV52265168; called by muse, mutect2, varscan2
- AUTS2 | c.2629C>T p.R877W | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754666556; called by muse, mutect2, varscan2
- BDKRB1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.806); catalogued as rs1322664878; called by muse, mutect2, varscan2
- CENPL | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs144722707; called by muse, mutect2, varscan2
- CFAP61 | c.1852G>A p.V618M | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747883044, COSV99845882; called by muse, mutect2, varscan2
- CHD5 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as rs751854770, COSV99311991; called by muse, mutect2, varscan2
- CHRNA4 | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs201673381; ClinVar: likely benign; called by muse, mutect2, varscan2
- CMYA5 | c.2653G>A p.E885K | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as rs768094007, COSV71409878; called by muse, mutect2, varscan2
- CUBN | c.6733G>A p.A2245T | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.06); catalogued as rs1237546086; called by muse, mutect2, varscan2
- DCAF4 | c.152C>T p.P51L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs758785720; called by mutect2, varscan2
- DENND2C | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs372971179; called by muse, mutect2, varscan2
- DHX40 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs772666485; called by muse, mutect2, varscan2
- DLGAP2 | c.1896G>T p.Q632H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1305290470; called by muse, mutect2, varscan2
- DMRTC2 | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs782073409, COSV99523260; called by muse, mutect2, varscan2
- ENAH | c.662G>A p.R221H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated, low confidence (0.2); catalogued as rs1195830663; called by muse, mutect2, varscan2
- EPHB2 | c.2608C>T p.R870W (on ENST00000400191 / NM_001309193.2; = p.R871W on NM_004442.7) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1353409966; called by muse, mutect2, varscan2
- FAM189B | c.1919G>A p.R640Q | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs766135947; called by muse, mutect2, varscan2
- FAM20A | c.949G>A p.A317T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs139437162; called by mutect2, varscan2
- FBN2 | c.3161G>A p.R1054H | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs753760095, COSV52517731; called by muse, mutect2, varscan2
- FCRL3 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs760139214; called by muse, mutect2, varscan2
- FKTN | c.766C>T p.R256* | Nonsense Mutation (SNP) | VAF 10/46 reads (22%) | catalogued as rs377417974, CM1312061; called by muse, mutect2, varscan2
- FLG | c.5972C>T p.A1991V | Missense Mutation (SNP) | VAF 86/319 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs556604607, COSV64246092; called by muse, mutect2, varscan2
- FLNB | c.3593C>T p.T1198M | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.045); catalogued as rs963229056, COSV55869550; called by muse, mutect2, varscan2
- FSIP2 | c.18403del p.C6135Vfs*4 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | catalogued as COSV100554213; called by mutect2, varscan2
- GABRA6 | c.1129C>A p.L377M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs374907395; called by muse, mutect2, varscan2
- GABRG1 | c.792del p.F264Lfs*3 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | catalogued as rs772301203; called by mutect2, varscan2
- GALNT8 | c.497C>T p.T166M | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.567); catalogued as rs201255097, COSV52896639; called by muse, mutect2, varscan2
- GPR85 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as rs774052608, COSV51784185, COSV51785166; called by muse, mutect2, varscan2
- HBS1L | c.1556G>A p.R519Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as rs772029883, COSV63200834; called by muse, mutect2, varscan2
- IL3 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 7/30 reads (23%) | PolyPhen benign (0); catalogued as rs780057953, COSV57309631; called by muse, mutect2, varscan2
- IPO13 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs761993293; called by muse, mutect2, varscan2
- LAMC3 | c.3019G>A p.G1007S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs141105450; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LPCAT2 | c.1240C>T p.R414* | Nonsense Mutation (SNP) | VAF 20/62 reads (32%) | catalogued as rs780823856, COSV50895398; called by muse, mutect2, varscan2
- MAGEE2 | c.615A>C p.K205N | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100973169; called by muse, mutect2, varscan2
- MKI67 | c.3982G>A p.G1328S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs201476882; called by muse, mutect2, varscan2
- MMP9 | c.1385C>T p.T462M | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV63433718; called by muse, mutect2
- MOV10L1 | c.1978C>T p.P660S | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53167306; called by muse, mutect2, varscan2
- MYOM1 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1355025966, COSV55285716; called by muse, mutect2, varscan2
- NBPF1 | c.2542T>A p.S848T | Missense Mutation (SNP) | VAF 52/341 reads (15%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.712); catalogued as rs774979031; called by muse, mutect2, varscan2
- NHSL2 | c.1172C>T p.P391L (on ENST00000510661; = p.P757L on NM_001013627.2) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs370237961; called by muse, mutect2, varscan2
- NLRP2 | c.1210G>A p.V404M | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs763533364, COSV54756745; called by muse, mutect2, varscan2
- NOLC1 | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.554); catalogued as rs759969277; called by muse, mutect2, varscan2
- NPFFR2 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.037); catalogued as COSV100440757; called by muse, mutect2, varscan2
- OXER1 | c.365G>A p.R122Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.601); catalogued as rs369449798; called by mutect2, varscan2
- PALLD | c.1260+1G>A p.X420_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | catalogued as COSV54983265; called by muse, mutect2, varscan2
- PARD3B | c.2023A>T p.S675C | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62504977, COSV62534042; called by muse, mutect2, varscan2
- PATJ | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760730885; called by muse, mutect2, varscan2
- PCDHGB3 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54057711; called by muse, mutect2, varscan2
- PCDHGB7 | c.1864C>T p.R622* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as COSV53959062; called by muse, mutect2, varscan2
- PCNT | c.8960G>A p.R2987Q | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs539546451; called by muse, varscan2
- PGC | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV63122962; called by muse, mutect2
- PTPRG | c.2060G>A p.G687E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55642204; called by muse, mutect2, varscan2
- PTPRT | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs756719404, COSV61991055; called by muse, mutect2, varscan2
- RCVRN | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs771263915, COSV99874130; called by muse, mutect2, varscan2
- RORA | c.652G>A p.V218I (on ENST00000335670 / NM_134261.3; = p.V243I on NM_002943.3) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.023); catalogued as rs140905032, COSV55036614; called by muse, mutect2, varscan2
- SCGB1D2 | c.197C>T p.T66M | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs774070276; called by muse, mutect2, varscan2
- SCN5A | c.3947G>A p.R1316Q (on ENST00000333535 / NM_198056.3; = p.R1315Q on NM_000335.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as rs765907469, CM143810, COSV100346967, COSV61139531; called by muse, mutect2, varscan2
- SDF4 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.184); catalogued as rs572222634, COSV55421120; called by muse, mutect2, varscan2
- SELP | c.928G>A p.G310R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55257933, COSV99740722; called by muse, mutect2, varscan2
- SHROOM2 | c.226G>A p.G76S | Missense Mutation (SNP) | VAF 29/40 reads (73%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs1047996391; called by muse, mutect2, varscan2
- SLC28A1 | c.1604C>T p.T535M | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757092813; called by muse, mutect2, varscan2
- SLC2A7 | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs370854911; called by muse, mutect2, varscan2
- SLC6A3 | c.1411G>A p.V471I | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.698); catalogued as rs75916702, COSV54361807; called by muse, mutect2, varscan2
- SMPD1 | c.122T>C p.L41P | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.522); catalogued as rs760549042; called by muse, varscan2
- SPACA1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.003); catalogued as rs145474393; called by muse, mutect2, varscan2
- SPOCD1 | c.3542G>A p.R1181H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs754159686, COSV57096251; called by muse, mutect2, varscan2
- SSTR3 | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs1469109472, COSV60729367; called by muse, mutect2, varscan2
- STAU1 | c.1460C>T p.T487M (on ENST00000371856 / NM_001319135.1; = p.T406M on NM_004602.3) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as rs1426079044; called by muse, mutect2, varscan2
- STYK1 | c.267G>C p.E89D | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV50014383; called by muse, mutect2, varscan2
- TANC1 | c.5534G>A p.S1845N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.651); catalogued as COSV99050449; called by mutect2, varscan2
- TBC1D22B | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs769361060, COSV100996760, COSV100997002; called by muse, mutect2, varscan2
- TBC1D2B | c.2785C>T p.R929W (on ENST00000300584 / NM_144572.1; = p.S911= on NM_015079.6) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs762151053; called by muse, mutect2, varscan2
- TCHH | c.3037C>T p.R1013C | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as rs773324878, COSV64272946; called by muse, mutect2, varscan2
- TEAD4 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1020125646; called by muse, mutect2, varscan2
- TIGD2 | c.128G>A p.R43H | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs758812379, COSV57648748; called by muse, mutect2, varscan2
- TLN2 | c.2488C>T p.R830W | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs568266946, COSV60890125; called by muse, mutect2, varscan2
- TRPM3 | c.1112C>T p.S371L (on ENST00000357533 / NM_001366142.2; = p.S216L on NM_020952.6) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.349); catalogued as rs774462289; called by muse, mutect2, varscan2
- ZXDA | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1345795692, COSV62388303; called by muse, mutect2, varscan2
- ABCA12 | c.6205G>A p.A2069T (on ENST00000272895 / NM_173076.3; = p.A1751T on NM_015657.3) | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AHCYL1 | c.21G>T p.M7I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- ALK | c.1030C>T p.H344Y | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- ARHGEF25 | c.1407_1408insT p.D470* | Frame Shift Ins (INS) | VAF 5/19 reads (26%) | called by mutect2, pindel, varscan2
- ASXL3 | c.374C>G p.T125S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AURKA | c.204C>G p.H68Q | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CENPQ | c.183A>T p.K61N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CEP170B | c.4718C>T p.P1573L (on ENST00000453495; = p.P1502L on NM_015005.3) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CHD9 | c.7891G>A p.G2631R (on ENST00000398510 / NM_001382353.1; = p.G2615R on NM_025134.7) | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CIC | c.916_919dup p.A307Gfs*9 | Frame Shift Ins (INS) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- CLIP4 | c.1616C>A p.S539Y | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- CUL4B | c.2684A>C p.D895A | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- DNAH17 | c.9389A>G p.E3130G | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- DNAH5 | c.10943T>C p.L3648P | Missense Mutation (SNP) | VAF 64/92 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DUSP10 | c.1253T>C p.I418T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ETFA | c.115A>C p.N39H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- FAM118B | c.126A>C p.E42D | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FANCM | c.5998A>T p.M2000L | Missense Mutation (SNP) | VAF 33/51 reads (65%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- GCNA | c.1043C>T p.A348V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRIA2 | c.1202A>T p.E401V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- HTR1D | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL2RA | c.262C>G p.R88G | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- ISM1 | c.1271T>C p.I424T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ITGAX | c.3307C>G p.H1103D | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.732); called by muse, mutect2, varscan2
- KCNF1 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- KRTAP10-5 | c.784T>G p.C262G | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KRTAP2-4 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LTBP3 | c.3608T>A p.L1203Q (on ENST00000301873 / NM_001130144.3; = p.L1156Q on NM_021070.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- MAGEE2 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- MYLIP | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NBPF9 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NFYA | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- NOP14 | c.835G>A p.A279T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- NRG3 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PCDHA1 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- PGR | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 13/207 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); called by muse, mutect2
- PIWIL3 | c.1388_1389insG p.N463Kfs*23 | Frame Shift Ins (INS) | VAF 11/54 reads (20%) | called by mutect2, pindel, varscan2
- PKLR | c.1437-1G>A p.X479_splice | Splice Site (SNP) | VAF 4/31 reads (13%) | called by muse, mutect2
- PKN2 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PNPLA8 | c.1820C>T p.A607V | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRELID2 | c.271C>T p.Q91* (on ENST00000334744 / NM_182960.4; = p.Q50* on NM_138492.6) | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- PRPF8 | c.4932G>T p.L1644F | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PSMB6 | c.694G>T p.A232S | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAD54L2 | c.703G>A p.V235I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.84); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RANBP2 | c.5714C>T p.P1905L | Missense Mutation (SNP) | VAF 60/386 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- RRBP1 | c.2865_2868del p.R956Sfs*59 (on ENST00000377813 / NM_001365613.2; = p.R523Sfs*59 on NM_004587.3) | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- RYR2 | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- STXBP5 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 46/105 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STYK1 | c.266A>G p.E89G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- TAAR5 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TEKT1 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- TRIML2 | c.781T>C p.C261R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- UBE2O | c.1204C>T p.P402S | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- UGT2B15 | c.330T>A p.F110L | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- ULK1 | c.951C>T p.S317= | Splice Region (SNP) | VAF 8/33 reads (24%) | called by muse, mutect2, varscan2
- UNC5D | c.2039G>A p.G680E | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UXS1 | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDR36 | c.89T>C p.V30A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2
- ZBTB49 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZCRB1 | c.157G>T p.V53F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- ZFP30 | c.334T>G p.C112G | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF107 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.338); called by muse, mutect2
- ZNF446 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.562); called by muse, mutect2, varscan2
- A4GALT | c.645C>T p.V215= | Silent (SNP) | VAF 23/39 reads (59%) | called by muse, mutect2, varscan2
- ALKAL1 | c.21C>T p.G7= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- ANKRD24 | c.2250C>T p.A750= | Silent (SNP) | VAF 32/51 reads (63%) | catalogued as rs1288281466; called by muse, mutect2, varscan2
- BAP1 | c.975C>T p.S325= | Silent (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- C16orf70 | c.418T>C p.L140= | Silent (SNP) | VAF 12/71 reads (17%) | called by muse, mutect2, varscan2
- C7orf50 | c.540G>A p.P180= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs553051427, COSV62477364; called by muse, mutect2, varscan2
- CARMIL1 | c.1336T>C p.L446= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as rs371805264; called by muse, mutect2, varscan2
- CASZ1 | c.429C>T p.G143= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs749040511, COSV59733549; called by muse, mutect2, varscan2
- CCDC12 | c.291C>T p.P97= (on ENST00000425441 / NM_001277074.1; = p.P110= on NM_144716.5) | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs551526667, COSV52765904; called by muse, mutect2, varscan2
- CNGB1 | c.366G>A p.T122= | Silent (SNP) | VAF 22/108 reads (20%) | catalogued as rs775701759; called by muse, mutect2, varscan2
- COL11A1 | c.4233C>A p.G1411= | Silent (SNP) | VAF 20/128 reads (16%) | called by muse, mutect2, varscan2
- COL4A6 | c.253C>T p.L85= | Silent (SNP) | VAF 22/41 reads (54%) | called by muse, mutect2, varscan2
- CUX2 | c.1413C>T p.D471= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs368575682; called by muse, mutect2, varscan2
- CWF19L2 | c.1407A>G p.L469= | Silent (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- DFFB | c.163C>T p.L55= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs1389848996; called by muse, mutect2, varscan2
- DYRK1B | c.282C>T p.D94= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs146381130; called by muse, mutect2, varscan2
- ERBB4 | c.603A>T p.T201= | Silent (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- FGFR2 | c.2073G>A p.V691= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- FOXA2 | c.744C>T p.Y248= (on ENST00000377115 / NM_153675.3; = p.Y254= on NM_021784.5) | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as rs773365412; called by mutect2, varscan2
- GAA | c.1941C>T p.C647= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as rs776948121, CM940802; called by muse, mutect2, varscan2
- GFRA2 | c.1242C>T p.N414= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- IL2RA | c.480C>T p.H160= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs775282989; called by muse, mutect2, varscan2
- IMPDH1 | c.927C>T p.A309= (on ENST00000470772 / NM_001142573.2; = p.A395= on NM_000883.4) | Silent (SNP) | VAF 9/60 reads (15%) | catalogued as rs1192343828; called by muse, mutect2, varscan2
- ITIH2 | c.2571C>T p.H857= | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as rs190130821, COSV64433247; called by muse, mutect2, varscan2
- KDM4A | c.729C>T p.T243= | Silent (SNP) | VAF 12/57 reads (21%) | called by muse, mutect2, varscan2
- KNDC1 | c.1095G>A p.P365= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as rs764989433, COSV58836668; called by muse, mutect2, varscan2
- LARP4B | c.2136G>A p.P712= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs749950846; called by muse, mutect2, varscan2
- LRP4 | c.4812C>T p.I1604= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs753496184, COSV66134302; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRWD1 | c.1185C>T p.I395= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs1455294736; called by muse, mutect2, varscan2
- MAGEA12 | c.588G>A p.V196= | Silent (SNP) | VAF 69/99 reads (70%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.558G>A p.Q186= | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- MC3R | c.651C>T p.H217= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as rs759015670, COSV99710809; called by muse, mutect2, varscan2
- NSUN6 | c.543C>A p.R181= | Silent (SNP) | VAF 21/106 reads (20%) | called by muse, mutect2, varscan2
- OMD | c.1095A>G p.Q365= | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- PCDHA9 | c.1353C>T p.N451= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs1554143388, COSV65324575; called by muse, mutect2, varscan2
- PLCD1 | c.261C>T p.F87= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs751305674; called by muse, mutect2, varscan2
- RBM27 | c.420C>T p.D140= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs549958493, COSV54590664; called by muse, mutect2, varscan2
- SHC4 | c.1605G>A p.A535= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs141070519; called by muse, mutect2, varscan2
- SIPA1L2 | c.4521C>T p.S1507= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as rs762162925, COSV53384613; called by muse, mutect2, varscan2
- SLC29A4 | c.627G>A p.A209= | Silent (SNP) | VAF 34/59 reads (58%) | called by muse, mutect2, varscan2
- SLC35F4 | c.825C>A p.A275= (on ENST00000339762 / NM_001352015.2; = p.A239= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/24 reads (13%) | catalogued as COSV100333885; called by muse, mutect2
- SLIT2 | c.3900C>T p.N1300= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs141395818, COSV56593779; called by mutect2, varscan2
- SLITRK5 | c.480C>T p.V160= | Silent (SNP) | VAF 12/21 reads (57%) | catalogued as rs191310383; called by muse, mutect2, varscan2
- TBX2 | c.1446G>A p.P482= | Silent (SNP) | VAF 5/64 reads (8%) | called by muse, mutect2
- TMEM223 | c.480G>A p.R160= | Silent (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- TNNI3K | c.2169C>A p.L723= | Silent (SNP) | VAF 21/74 reads (28%) | catalogued as COSV53946062; called by muse, mutect2, varscan2
- UNC13C | c.810C>G p.L270= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV52934367; called by muse, mutect2, varscan2
- ZNF675 | c.1281A>G p.E427= | Silent (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2, varscan2
- ATP2B2 | c.*53C>T | 3'UTR (SNP) | VAF 6/36 reads (17%) | catalogued as rs1294453195, COSV100659925; called by muse, mutect2, varscan2
- BOLA3 | c.*14G>T | 3'UTR (SNP) | VAF 6/56 reads (11%) | catalogued as COSV99768271; called by mutect2, varscan2
- CTBP2 | c.58+12146A>T | Intron (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2
- GBA2 | c.-509C>A | 5'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- OBSCN | c.18662-2619G>A | Intron (SNP) | VAF 7/53 reads (13%) | catalogued as rs766143835; called by muse, mutect2, varscan2
- S1PR3 | c.-301G>A | 5'UTR (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- SNORD114-6 | n.42G>T | RNA (SNP) | VAF 6/38 reads (16%) | catalogued as rs755176547; called by muse, mutect2, varscan2
- STAG3L4 | n.371G>A | RNA (SNP) | VAF 10/50 reads (20%) | called by muse, mutect2, varscan2
